Somatic mutation profile of tumor specimen 0DUXPO from CCDI case PBCLJR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.0 years (4,368 days).
Specimen 0DUXPO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbaeadad-22af-4fee-9d94-1b49cf942c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/022d8b1e-9b74-4897-9921-0cc71e4edfa4

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 143/420 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs756449768; called by muse, mutect2, varscan2
- EMG1 | c.271_272del p.X91_splice | Splice Site (DEL) | VAF 51/227 reads (22%) | catalogued as rs1449132123; called by pindel, varscan2
- FAM160A1 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 141/471 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs369369956; called by muse, mutect2, varscan2
- FAM83H | c.2851G>A p.A951T | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs374325568; called by muse, mutect2, varscan2
- FBP2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs550526190, COSV64695235; called by muse, mutect2, varscan2
- HCN1 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100298940; called by muse, mutect2
- OR2L2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as rs753145578, COSV63551776; called by muse, mutect2, varscan2
- PMEL | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.936); catalogued as COSV100093061; called by muse, mutect2, varscan2
- SPTA1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs765819340, COSV100935290; called by muse, mutect2
- ZNF799 | c.1153A>G p.T385A | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1220850783; called by muse, mutect2, varscan2
- ZP3 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs370377360; called by muse, mutect2
- ALB | c.843+4A>G | Splice Region (SNP) | VAF 28/414 reads (7%) | called by muse, mutect2
- MAP3K4 | c.3284G>T p.G1095V | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYH4 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 26/760 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- CNOT6L | c.1383A>T p.T461= (on ENST00000504123 / NM_001286790.2; = p.T456= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/418 reads (6%) | called by muse, mutect2
- EPS8 | c.1314G>A p.E438= | Silent (SNP) | VAF 74/327 reads (23%) | catalogued as rs369560821; called by muse, mutect2, varscan2
- MMS22L | c.2334C>A p.I778= | Silent (SNP) | VAF 34/424 reads (8%) | catalogued as COSV51524843; called by muse, mutect2
- STAB1 | c.702C>T p.N234= | Silent (SNP) | VAF 15/373 reads (4%) | called by muse, mutect2
- WDR87 | c.1864C>T p.L622= | Silent (SNP) | VAF 37/313 reads (12%) | called by muse, mutect2, varscan2
